Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A4U4, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A4U4-06A (Metastatic).

[page 1 of 4]
SPECIMEN(S):

- A. RIGHT AXILLARY L.N. DISECTION LEVELS 1,2,3
- B. WIDE EXCISION RIGHT CHEST WALL MELANOMA

CLINICAL HISTORY:

None given

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary
c77.3

PRE-OPERATIVE DIAGNOSIS:

Melanoma

10/10/12
fu

DIAGNOSIS:

A. LYMPH NODES, RIGHT AXILLARY, LEVELS 1,2,3, DISECTION:

- TWO OF FORTY-FOUR LYMPH NODES POSITIVE FOR MALIGNANT MELANOMA (2/44)
- MACROMETASTASIS INVOLVING COMPLETELY BOTH LYMPH NODES WITH FOCAL EXTRA-NODAL EXTENSION.

B. SKIN, RIGHT CHEST WALL, MELANOMA, WIDE EXCISION:

- NO RESIDUAL MELANOMA IS IDENTIFIED.
- PREVIOUS BIOPSY SITE CHANGES.

Comment:

Immunostain A103 performed on the block A10 and reported on the table below support the above diagnosis.

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

[page 2 of 4]
Material: Block A10

Population: Tumor Cells

Stain/Marker:

Result:

Comment:

A103,MELAN-A

Negative

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within

The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by th

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and/or negative controls.

[page 3 of 4]
GROSS DESCRIPTION:

A. RIGHT AXILLARY L.N. DISECTION LEVELS 1,2,3

Received fresh labeled with the patient's identification and designated "right axillary lymph node dissection levels I, II, III" is a portion of fibroadipose tissue measuring 16 x 8.4 x 2 cm. Multiple possible lymph nodes are identified ranging from 0.3 x 0.3 x 0.2 cm up to 2.5 x 2 x 1.4 cm. One half of the largest lymph node is submitted for tissue procurement. Cassettes are submitted as follows:

A1: 6 possible lymph nodes

A2: 5 possible lymph nodes

A3: 5 possible lymph nodes

A4: 4 possible lymph nodes

A5: 4 possible lymph nodes

A6: 2 possible lymph nodes

A7: 2 possible lymph nodes

A8: One bisected lymph node

A9: One bisected lymph node

A10: One bisected lymph node

A11: One bisected lymph node

A12: One bisected lymph node

A13: One bisected lymph node

A14-A15: Remainder of largest lymph node, entirely submitted

B. WIDE EXCISION RIGHT CHEST WALL MELANOMA

Received fresh with the patient's identification and designated "wide excision right chest wall melanoma" is a tan-white skin ellipse measuring 7.2 x 3.1 x 1.6 cm. The specimen is oriented with a stitch at the lateral margin. Examination of the skin surface reveals a tan-pink, irregular, flat lesion measuring 2.5 x 1.6 cm. Gross picture is taken. The specimen is inked green from medial to lateral and orange from lateral to medial. The specimen is serially sectioned from medial to lateral and submitted in 12 cassettes after submitting a portion of the specimen for tissue procurement.

[page 4 of 4]
B1: Medial margin

B2- B4: Entire sections

B5-B10: Upper and lower 1/3rds of the sections

B11: entire section

B12: Lateral margin.

10/10/12

Source: NCI Genomic Data Commons file e71f35d9-4e3b-4208-ae28-da0ca11ef694 (TCGA-GN-A4U4.FEA743A2-070D-48B1-BB64-8E2A0044B170.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).